Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A625, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A625-01A (Primary Tumor).

Gross Description: Tumor is located in lower esophagus nearby of Z lines. It is ulcerated and protruded, with 3x2x1.5cm in size, soft and white-gray surface.

Microscopic Description: Squamous cell layer is ulcerated or hyperplastic. Tumor tissue arranges in the form of group or sheets or trabecular of tumor cells. The malignant cells have moderate, light eosinophilic cytoplasm. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are common. Tumor invades in fat tissue. Stroma is invasion of lymphocytes.

Diagnosis Details: Squamous cell carcinoma, Grade II, infiltrating fat tissue

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Abdominal esophagus

Tumor size: 3 x 2 x 1.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 5/8 positive for metastasis (Regional 5/8)

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, squamous cell NOS
887613
Site: Lower third of esophagus
C15.5
gaw 4/12/13

ILPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 634b24d1-a7d3-4a58-8212-699e479c566e (TCGA-IG-A625.0F8E354D-389D-4297-80E8-DBE7629A7D71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).